Gene-level copy-number profile of tumor specimen TCGA-AG-3581-01A from TCGA case TCGA-AG-3581, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 63.9 years (23,345 days).
Specimen TCGA-AG-3581-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.4f299634-416e-412f-b480-893090380807.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3581-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eefaa6bb-6370-4d05-8caa-644860bf06f0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,128; copy number 2: 40,900; copy number 3: 5,778; copy number 4: 996; copy number 6: 5; copy number 7: 6.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-3581-01A-01D-0819-01): tumor purity 0.65, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,256,337–38,276,318, 5 genes, copy number 6: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1.
- chr17:22,671,433–27,003,259, 6 genes, copy number 7: AC131274.3, AC131274.1, AC131274.2, AC069061.1, AC069061.2, PDLIM1P3.

Autosomal genes at a single copy (total copy number 1): 9,741. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
